Somatic mutation profile of tumor specimen TCGA-FS-A4FC-06A (aliquot TCGA-FS-A4FC-06A-11D-A24R-08) from TCGA case TCGA-FS-A4FC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.8 years (28,791 days).
Specimen TCGA-FS-A4FC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52174a15-c841-493c-a8b1-15a6a8f0da24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4FC-10A (Blood Derived Normal), aliquot TCGA-FS-A4FC-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7c095e8-a65e-4c0c-8703-8f335978def2

The open-access MAF lists 863 somatic variants for this specimen: 583 protein-altering or splice-affecting, 263 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 518, Silent 263, Nonsense Mutation 41, Splice Site 10, Splice Region 10, Intron 6, 5'Flank 3, 3'UTR 3, RNA 3, 5'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (750 of 863; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 55/150 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OCRL | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 55/137 reads (40%) | catalogued as rs1556346316, CM990983, COSV63980169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2
- A2M | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59391841; called by muse, varscan2
- A2ML1 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369978459; called by muse, mutect2, varscan2
- ABCA12 | c.5494G>A p.E1832K (on ENST00000272895 / NM_173076.3; = p.E1514K on NM_015657.3) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV55970836; called by muse, mutect2, varscan2
- ABCA12 | c.1444G>A p.E482K (on ENST00000272895 / NM_173076.3; = p.E164K on NM_015657.3) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as rs150321357; called by muse, mutect2, varscan2
- ABCC8 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1404720025, CD025928, COSV56856721; called by muse, mutect2, varscan2
- AC008397.2 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868304717, COSV53209446; called by muse, mutect2, varscan2
- ACE | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52012536; called by muse, mutect2, varscan2
- ACP4 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs201115271, COSV54517784; called by muse, mutect2, varscan2
- ADAD1 | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs757098217, COSV56646939; called by muse, mutect2, varscan2
- ADAMDEC1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 74/224 reads (33%) | catalogued as rs376286647, COSV56474636; called by muse, mutect2, varscan2
- ADAMTS10 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs550484994, COSV54351617; called by muse, mutect2, varscan2
- ADAMTS12 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV100711552; called by muse, mutect2, varscan2
- ADGRE1 | c.2551-1G>A p.X851_splice | Splice Site (SNP) | VAF 39/160 reads (24%) | catalogued as COSV51680341, COSV99165019; called by muse, mutect2, varscan2
- ADGRV1 | c.4400G>A p.G1467E | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM140611, COSV67994117; called by muse, mutect2, varscan2
- ADGRV1 | c.9770C>T p.S3257F | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV67994124; called by muse, mutect2, varscan2
- AGAP3 | c.1872C>G p.N624K (on ENST00000622464; = p.N660K on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV68246479; called by muse, mutect2, varscan2
- AHNAK | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV57228023; called by muse, mutect2, varscan2
- AHR | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54126014; called by muse, mutect2, varscan2
- AKAP14 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57631180; called by muse, mutect2, varscan2
- AKR1C2 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1554773538, COSV101060363; called by muse, mutect2, varscan2
- AL117348.2 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1336451314, COSV55283768; called by muse, mutect2, varscan2
- AL121899.2 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV67352195; called by muse, mutect2, varscan2
- ALDH1A2 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963837318, COSV51083900; called by muse, mutect2, varscan2
- ALK | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs760717114, COSV66587239; called by muse, mutect2, varscan2
- AMPD3 | c.52C>T p.R18W (on ENST00000396553 / NM_001025389.2; = p.R27W on NM_000480.3) | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV67329916; called by muse, mutect2, varscan2
- ANK3 | c.10338G>A p.W3446* | Nonsense Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as COSV55078735; called by muse, mutect2, varscan2
- ANK3 | c.3487C>T p.Q1163* (on ENST00000280772 / NM_001320874.2; = p.Q297* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | catalogued as COSV55070310; called by muse, mutect2, varscan2
- ANKRD22 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs748983467, COSV64236397; called by muse, mutect2, varscan2
- ANLN | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV56079055; called by muse, mutect2, varscan2
- APBB1IP | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63304235; called by muse, mutect2, varscan2
- AQP10 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs752776491, COSV61476042; called by muse, mutect2
- ARHGAP21 | c.4475C>T p.S1492L | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57610476; called by muse, mutect2, varscan2
- ARHGAP31 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV51798245; called by muse, mutect2, varscan2
- ARHGEF11 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); catalogued as rs1362978048, COSV63815352; called by muse, mutect2, varscan2
- ARID2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 38/100 reads (38%) | catalogued as COSV57596634; called by muse, mutect2, varscan2
- ARID2 | c.2881C>T p.Q961* | Nonsense Mutation (SNP) | VAF 40/190 reads (21%) | catalogued as COSV57595985; called by muse, mutect2, varscan2
- ARID2 | c.3536A>T p.N1179I | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as COSV57613320; called by muse, mutect2, varscan2
- ARIH2 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV62706154; called by muse, mutect2, varscan2
- ARMS2 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs774278306, COSV73307029; called by muse, mutect2, varscan2
- ART3 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61915682; called by muse, mutect2, varscan2
- ASB15 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV51928767; called by muse, mutect2, varscan2
- ASPM | c.5137C>T p.R1713C | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs143911853; called by muse, mutect2, varscan2
- ASPRV1 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs767723379, COSV57229028; called by muse, mutect2, varscan2
- ASTN1 | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs944529041, COSV56061495; called by muse, mutect2, varscan2
- ASXL3 | c.4852G>A p.G1618R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV52477882; called by muse, mutect2, varscan2
- ATG9B | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as rs1224215613, COSV52509680; called by muse, mutect2
- ATP13A4 | c.301T>A p.F101I | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV55074530; called by muse, mutect2, varscan2
- ATP6V1C2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV55364498; called by muse, mutect2, varscan2
- ATP8B1 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV52179578; called by muse, mutect2, varscan2
- ATP8B3 | c.3851C>T p.S1284F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.364); catalogued as COSV59547933; called by muse, mutect2, varscan2
- ATXN2L | c.1576A>C p.I526L | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV57378217; called by muse, mutect2, varscan2
- AXDND1 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs776158906, COSV62641243; called by muse, mutect2, varscan2
- AXDND1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV62647649; called by muse, mutect2, varscan2
- B3GNT5 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as COSV58476886; called by muse, mutect2, varscan2
- B4GALNT2 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV55928018; called by muse, mutect2, varscan2
- BAHCC1 | c.3359C>T p.T1120I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV57032624; called by muse, mutect2, varscan2
- BBOX1 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54193573; called by muse, mutect2, varscan2
- BMP6 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51671704; called by muse, mutect2, varscan2
- BPGM | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305552961, COSV61326066; called by muse, mutect2, varscan2
- BPTF | c.5290C>T p.P1764S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV58845698; called by muse, mutect2, varscan2
- BTBD11 | c.2278G>A p.D760N (on ENST00000280758 / NM_001018072.2; = p.D297N on NM_001017523.2) | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs910412555, COSV55035740; called by muse, mutect2, varscan2
- BUD13 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV52768357; called by muse, mutect2, varscan2
- C10orf120 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1487424360, COSV61491704; called by muse, mutect2, varscan2
- C10orf120 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV61491918, COSV61491926; called by muse, mutect2, varscan2
- C1orf94 | c.1048G>A p.G350R (on ENST00000488417 / NM_001134734.2; = p.G160R on NM_032884.5) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs376456709; called by muse, mutect2, varscan2
- C2orf78 | c.2588C>T p.P863L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV68519164; called by muse, mutect2, varscan2
- CAB39L | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV61716609; called by muse, mutect2, varscan2
- CABCOCO1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.802); catalogued as rs1289630799, COSV57595758; called by muse, mutect2, varscan2
- CACNA1C | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59763891; called by muse, mutect2, varscan2
- CACNA1G | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV61737445; called by muse, mutect2, varscan2
- CALCRL | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV66475296; called by muse, mutect2, varscan2
- CAMSAP3 | c.2425C>T p.H809Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50356642; called by muse, mutect2, varscan2
- CAND1 | c.1347G>C p.K449N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV73389771; called by muse, mutect2, varscan2
- CAT | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV53812999; called by muse, mutect2, varscan2
- CBFA2T2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60075498; called by muse, mutect2, varscan2
- CCDC126 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748345955, COSV56739913; called by muse, mutect2, varscan2
- CCDC30 | c.607G>A p.E203K (on ENST00000340612; = p.E160K on NM_001080850.3) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV59609043; called by muse, mutect2, varscan2
- CCDC88C | c.2922G>A p.M974I | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66241225; called by muse, mutect2, varscan2
- CCNB3 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV52079046; called by muse, mutect2, varscan2
- CCT8L2 | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63463669; called by muse, mutect2, varscan2
- CD163 | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765023451, COSV63134443; called by muse, mutect2, varscan2
- CD300LG | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.036); catalogued as rs767557360, COSV53222930; called by muse, mutect2, varscan2
- CD6 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs368928420; called by muse, mutect2, varscan2
- CDC40 | c.1451A>G p.Q484R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as COSV57011924; called by muse, mutect2, varscan2
- CDH18 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs868527442, COSV56907663, COSV56951940; called by muse, mutect2, varscan2
- CDH4 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64672225; called by muse, mutect2, varscan2
- CDH4 | c.2627C>T p.T876I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64672232; called by muse, mutect2, varscan2
- CDHR5 | c.2380G>A p.E794K (on ENST00000358353 / NM_001171968.2; = p.E800K on NM_021924.5) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as rs753083717, COSV57645863; called by muse, mutect2, varscan2
- CDKL4 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as rs1253894115, COSV66510915; called by muse, mutect2, varscan2
- CDRT1 | c.1027A>G p.N343D | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.525); catalogued as rs546763049, COSV55413358; called by muse, mutect2
- CELSR2 | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156259026, COSV54778746; called by muse, mutect2, varscan2
- CFAP91 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as COSV56344247; called by muse, mutect2, varscan2
- CHIC2 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs761158928, COSV55756281; called by muse, mutect2, varscan2
- CHP1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as rs748050129, COSV58158301; called by muse, mutect2, varscan2
- CHRM5 | c.1340T>C p.I447T | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67248528; called by muse, mutect2, varscan2
- CHST8 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52862754; called by muse, mutect2, varscan2
- CIB2 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51949410; called by muse, mutect2, varscan2
- CLVS2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51568333; called by muse, mutect2, varscan2
- CNGA3 | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55627790; called by muse, mutect2, varscan2
- CNOT1 | c.4966A>T p.I1656L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV55321772; called by muse, mutect2, varscan2
- CNTN1 | c.1077C>G p.I359M | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); catalogued as COSV100751232, COSV61644882; called by muse, mutect2, varscan2
- COG4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs149620212; called by muse, mutect2, varscan2
- COL22A1 | c.4468G>A p.A1490T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1464464862, COSV57357095; called by muse, mutect2, varscan2
- COL4A2 | c.3124C>T p.P1042S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as rs1343473958, COSV64628474, COSV64633989; called by muse, mutect2, varscan2
- COL5A1 | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs141301771, COSV65673913; called by muse, mutect2, varscan2
- COL6A5 | c.5932G>A p.E1978K (on ENST00000312481; = p.E1974K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV55214733; called by muse, mutect2, varscan2
- CPZ | c.370G>A p.G124S (on ENST00000360986 / NM_001014447.3; = p.G113S on NM_003652.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs775424096, COSV59925769; called by muse, mutect2, varscan2
- CR1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as COSV65462494; called by muse, mutect2, varscan2
- CRISP1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59994917; called by muse, mutect2, varscan2
- CRYBG2 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.267); catalogued as COSV57489467; called by muse, mutect2, varscan2
- CSF3R | c.2345C>T p.P782L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58971295; called by muse, mutect2, varscan2
- CSMD3 | c.8240G>A p.W2747* | Nonsense Mutation (SNP) | VAF 30/97 reads (31%) | catalogued as COSV52299571; called by muse, mutect2, varscan2
- CTNNA2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs1490230233, COSV58151424; called by muse, mutect2, varscan2
- CTSO | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 41/173 reads (24%) | catalogued as COSV70809622; called by muse, mutect2, varscan2
- CYB5D2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56800934; called by muse, mutect2, varscan2
- CYP4F8 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV57855250; called by muse, mutect2, varscan2
- DACH1 | c.1324C>T p.P442S (on ENST00000619232 / NM_001366712.1; = p.P390S on NM_080759.6) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as rs747753827, COSV57493215; called by muse, mutect2, varscan2
- DAG1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.841); catalogued as COSV58183345; called by muse, mutect2, varscan2
- DBT | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs181239040, COSV64495358; called by muse, mutect2, varscan2
- DCAF4 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1030940900, COSV62319826; called by muse, mutect2, varscan2
- DCAF4L1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV60788434; called by muse, mutect2, varscan2
- DCDC1 | c.2245G>A p.G749R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1226626253, COSV60856556; called by muse, mutect2, varscan2
- DEPDC5 | c.2776C>T p.R926C (on ENST00000400246; = p.R995C on NM_014662.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1440528127, COSV56709326; called by muse, mutect2, varscan2
- DES | c.639+1G>A p.X213_splice | Splice Site (SNP) | VAF 22/85 reads (26%) | catalogued as rs868785776, COSV64660019; called by muse, mutect2, varscan2
- DEUP1 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV53216062; called by muse, mutect2, varscan2
- DGKI | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs760167594, COSV55937658; called by muse, mutect2, varscan2
- DGKI | c.2011A>G p.T671A | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55972461; called by muse, mutect2, varscan2
- DIP2A | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as rs1413142941, COSV59485917; called by muse, mutect2, varscan2
- DISP1 | c.3035C>T p.A1012V | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as rs1387200351, COSV52664286; called by muse, mutect2, varscan2
- DLG3 | c.2413T>C p.S805P (on ENST00000374360 / NM_021120.4; = p.S500P on NM_020730.3) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52086572; called by muse, mutect2, varscan2
- DLG4 | c.869C>T p.S290F (on ENST00000399506 / NM_001321075.3; = p.S333F on NM_001365.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV57240311; called by muse, mutect2
- DLX2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV52232793; called by muse, mutect2, varscan2
- DMBT1 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 163/310 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs1039580642, COSV57559150; called by muse, mutect2, varscan2
- DMBT1 | c.6407C>T p.S2136F (on ENST00000338354 / NM_001377530.1; = p.S1379F on NM_004406.3) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV57534952; called by muse, mutect2, varscan2
- DMXL2 | c.5383C>T p.P1795S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51854813; called by muse, mutect2, varscan2
- DNAH2 | c.7054G>A p.D2352N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV66725971; called by muse, mutect2, varscan2
- DNAH2 | c.13276G>A p.D4426N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV66725978; called by muse, mutect2, varscan2
- DNAH5 | c.9853G>A p.E3285K | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV54248362; called by muse, mutect2, varscan2
- DNAH5 | c.5536C>T p.L1846F | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54248371; called by muse, mutect2, varscan2
- DNAH5 | c.3490C>T p.P1164S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs370578193, COSV99443610; called by muse, mutect2, varscan2
- DNAH7 | c.3406G>A p.A1136T | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV56782859; called by muse, mutect2, varscan2
- DNAH9 | c.7139G>T p.W2380L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52373855; called by muse, mutect2, varscan2
- DOCK6 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV52949613; called by muse, mutect2, varscan2
- DOK5 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1416515891, COSV52824901; called by muse, mutect2, varscan2
- DPH6 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56618870; called by muse, mutect2, varscan2
- DPYD | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60083070; called by muse, mutect2, varscan2
- DRD5 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV58578632; called by muse, mutect2, varscan2
- DSC3 | c.2313G>A p.M771I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs867992638, COSV64572539; called by muse, mutect2, varscan2
- DSEL | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59492615, COSV59494219; called by muse, mutect2, varscan2
- DSG3 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs866853810, COSV57129277; called by muse, mutect2, varscan2
- DSP | c.4567G>A p.E1523K | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV65795406; called by muse, mutect2, varscan2
- DUSP1 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV53321087; called by muse, mutect2, varscan2
- DYNC2H1 | c.12437C>T p.A4146V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV62105162; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); catalogued as rs762347103, COSV62570560; called by muse, mutect2, varscan2
- EEF1G | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV61323157; called by muse, mutect2, varscan2
- EFCAB13 | c.303+1G>A p.X101_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as rs1403356348, COSV58952170; called by muse, mutect2
- EFCAB6 | c.4237G>A p.E1413K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV53071398; called by muse, mutect2, varscan2
- EIF3A | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1398665610, COSV64962606, COSV64963114; called by muse, mutect2, varscan2
- EIF5B | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV56816386; called by muse, mutect2, varscan2
- ELAVL2 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as COSV56365527, COSV56369802; called by muse, mutect2, varscan2
- ELOA2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765481551, COSV55300627; called by muse, mutect2, varscan2
- ELOVL4 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100876318, COSV63954624; called by muse, mutect2, varscan2
- EPHA6 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67585203; called by muse, mutect2
- EPHB4 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639622; called by muse, mutect2
- EPPK1 | c.1789G>A p.G597S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.022); catalogued as COSV101599937; called by muse, mutect2, varscan2
- ERC1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61699017; called by muse, mutect2, varscan2
- ESRRA | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1469677687, COSV50008029; called by muse, mutect2, varscan2
- ETFB | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1568471932, COSV52468106; called by muse, mutect2, varscan2
- EXPH5 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.373); catalogued as COSV56207561; called by muse, mutect2, varscan2
- F8 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV64270860; called by muse, mutect2, varscan2
- FAAH | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs200701500; called by muse, mutect2, varscan2
- FAM135B | c.3755G>A p.G1252E | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52720445, COSV52742237; called by muse, mutect2, varscan2
- FAM71B | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV57230098; called by muse, varscan2
- FAM71B | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV57230074; called by muse, varscan2
- FAM90A1 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs746640938, COSV56714538; called by muse, mutect2, varscan2
- FAM90A1 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.982); catalogued as COSV56713245; called by muse, mutect2, varscan2
- FASLG | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60679817; called by muse, mutect2, varscan2
- FAT3 | c.5548C>T p.H1850Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV53093612; called by muse, mutect2, varscan2
- FAT4 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67881889; called by muse, mutect2, varscan2
- FBN2 | c.5677C>T p.R1893C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV52498971; called by muse, mutect2, varscan2
- FBN2 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs866719857, COSV52499675, COSV52517342, COSV99331150; called by muse, mutect2, varscan2
- FBXL20 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV52903634; called by muse, mutect2, varscan2
- FCGRT | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs758671395, COSV54541247; called by muse, mutect2, varscan2
- FCHO1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV53185052; called by muse, mutect2, varscan2
- FGD5 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV53250934, COSV99549633; called by muse, mutect2, varscan2
- FGD5 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs376575642; called by muse, mutect2, varscan2
- FGF20 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51662199; called by muse, mutect2, varscan2
- FLG | c.4687G>A p.E1563K | Missense Mutation (SNP) | VAF 133/461 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV100911527, COSV64242286; called by muse, mutect2, varscan2
- FLG2 | c.5465G>A p.R1822Q | Missense Mutation (SNP) | VAF 130/453 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.42); catalogued as rs780770917, COSV66171480, COSV66174376; called by muse, mutect2, varscan2
- FLG2 | c.4865G>A p.G1622E | Missense Mutation (SNP) | VAF 121/527 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV66172442; called by muse, mutect2, varscan2
- FOXR2 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.427); catalogued as rs1415494590, COSV59259582; called by muse, mutect2, varscan2
- FRYL | c.7073C>T p.T2358I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51960329; called by muse, mutect2, varscan2
- GABRB2 | c.1303G>A p.D435N (on ENST00000274547; = p.D397N on NM_000813.3) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as rs1274082991, COSV50939355; called by muse, mutect2, varscan2
- GABRG3 | c.1398T>A p.Y466* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100409348; called by muse, mutect2, varscan2
- GABRG3 | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1475640892, COSV61510792; called by muse, mutect2, varscan2
- GAP43 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV59343626; called by muse, mutect2, varscan2
- GATA2 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV62006706; called by muse, mutect2, varscan2
- GCSAML | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1427262828, COSV63577953, COSV63579783; called by muse, mutect2, varscan2
- GDF11 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV57690574; called by muse, mutect2, varscan2
- GFRAL | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1365247688, COSV61234906; called by muse, mutect2, varscan2
- GIMAP8 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV56229517; called by muse, mutect2, varscan2
- GJB3 | c.533T>A p.I178N | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64904835; called by muse, mutect2, varscan2
- GLB1L2 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV60280419; called by muse, mutect2, varscan2
- GLP2R | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV52328976; called by muse, mutect2
- GLYCTK | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59794698; called by muse, mutect2, varscan2
- GNAT3 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV68069986; called by muse, mutect2, varscan2
- GON4L | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV55202599; called by muse, mutect2, varscan2
- GPLD1 | c.490+4C>T | Splice Region (SNP) | VAF 16/44 reads (36%) | catalogued as COSV57760411; called by muse, mutect2, varscan2
- GPR161 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54793873; called by muse, mutect2, varscan2
- GPR35 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.057); catalogued as COSV60578416; called by muse, mutect2, varscan2
- GPRC6A | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59954029; called by muse, mutect2, varscan2
- GRID1 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV60049741; called by muse, mutect2, varscan2
- GRIK2 | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV59767468; called by muse, mutect2
- GRIK4 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV70806597; called by muse, mutect2, varscan2
- GRIN2A | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV58054632, COSV58055456; called by muse, mutect2, varscan2
- GRIN3A | c.1824G>A p.W608* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as rs868691206, COSV62450706; called by muse, mutect2, varscan2
- GRK4 | c.967C>T p.R323C (on ENST00000398052 / NM_182982.3; = p.R291C on NM_005307.3) | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs778034681, COSV61667976; called by muse, mutect2, varscan2
- GRM3 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV64478689; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV57032152; called by muse, mutect2, varscan2
- GUCY1A2 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs776789438, COSV56478434; called by muse, mutect2, varscan2
- HAO1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV66493136; called by muse, mutect2, varscan2
- HCN1 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.014); catalogued as COSV57509367; called by muse, mutect2, varscan2
- HECW1 | c.3799G>A p.V1267M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV67830083, COSV67838791; called by muse, mutect2, varscan2
- HEPH | c.3457C>T p.L1153F (on ENST00000343002; = p.L886F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57971047; called by muse, mutect2, varscan2
- HFM1 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV54036011; called by muse, mutect2, varscan2
- HIPK4 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs145519209; called by muse, mutect2, varscan2
- HIRA | c.2714C>T p.S905F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.899); catalogued as COSV54278841; called by muse, mutect2, varscan2
- HIVEP2 | c.5693C>T p.S1898F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50050511; called by muse, mutect2, varscan2
- HLCS | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60793115; called by muse, mutect2, varscan2
- HSDL1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs748798471, COSV54742040; called by muse, mutect2, varscan2
- HTR2C | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52222738; called by muse, mutect2, varscan2
- HTR7 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV53291153; called by muse, mutect2, varscan2
- HYDIN | c.7538G>A p.R2513K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0.038); catalogued as COSV59250556; called by muse, mutect2, varscan2
- IBTK | c.560T>A p.F187Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV60395665; called by muse, mutect2, varscan2
- ICA1 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs1216728776, COSV55583687; called by muse, mutect2, varscan2
- IFNAR2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV51617732; called by muse, mutect2, varscan2
- IFT57 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.807); catalogued as COSV52712189; called by muse, mutect2, varscan2
- IGSF3 | c.3433C>T p.L1145F (on ENST00000369486 / NM_001007237.3; = p.L1165F on NM_001542.4) | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59597779; called by muse, mutect2, varscan2
- IL5RA | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56522811; called by muse, mutect2, varscan2
- IL7R | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1451953167, COSV57407826; called by muse, mutect2, varscan2
- INSC | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs777486831, COSV101089566, COSV65409477; called by muse, mutect2, varscan2
- INSRR | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 33/141 reads (23%) | catalogued as rs201715497, COSV63871157; called by muse, mutect2, varscan2
- INTS3 | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.271); catalogued as COSV59681167; called by muse, mutect2, varscan2
- IQCH | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as COSV60059140; called by muse, mutect2, varscan2
- IQUB | c.2094G>A p.M698I | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs768691029, COSV61242344; called by muse, varscan2
- ITGA1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV50895585; called by muse, mutect2, varscan2
- ITGA4 | c.1566T>A p.D522E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52003581; called by muse, mutect2, varscan2
- ITGAE | c.2501A>T p.Q834L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as rs1244010885, COSV53999164; called by muse, mutect2, varscan2
- ITGAM | c.3233C>T p.S1078F (on ENST00000648685 / NM_001145808.2; = p.S1077F on NM_000632.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54941809; called by muse, mutect2, varscan2
- ITGAX | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51650812; called by muse, mutect2
- ITGB3 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs943122888, COSV71383379, COSV71385182; called by muse, mutect2, varscan2
- ITGB3 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV71383888; called by muse, mutect2, varscan2
- ITGB8 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV56013646; called by muse, mutect2, varscan2
- ITPR1 | c.7498G>A p.E2500K (on ENST00000354582; = p.E2445K on NM_002222.7) | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.041); catalogued as COSV56983282, COSV57001160; called by muse, mutect2, varscan2
- JCAD | c.3470C>T p.P1157L | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1477333487, COSV64761438; called by muse, mutect2, varscan2
- JMJD1C | c.6459A>C p.L2153F | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV59517626; called by muse, mutect2, varscan2
- KCND3 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV56188605; called by muse, mutect2, varscan2
- KCNH7 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868365205, COSV59811411; called by muse, mutect2, varscan2
- KCNJ15 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.099); catalogued as COSV60811838; called by muse, mutect2, varscan2
- KCNK10 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.72); catalogued as COSV56638797; called by muse, mutect2, varscan2
- KCNU1 | c.1629C>T p.A543= | Splice Region (SNP) | VAF 9/36 reads (25%) | catalogued as COSV67759425; called by muse, mutect2
- KIAA0513 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50743857; called by muse, mutect2, varscan2
- KIR3DL2 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 132/504 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs778873577, COSV99552284; called by muse, mutect2, varscan2
- KL | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV66309913; called by muse, mutect2, varscan2
- KLF6 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs772132474, COSV51496061; called by muse, mutect2, varscan2
- KRT3 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58817043; called by muse, mutect2, varscan2
- KRTAP5-3 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV68791184; called by muse, mutect2, varscan2
- KTN1 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | catalogued as COSV68025383; called by muse, mutect2, varscan2
- LAMA5 | c.954C>T p.F318= | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as COSV53371007; called by muse, mutect2
- LAMB1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774870882, COSV55964026, COSV55964780; called by muse, mutect2, varscan2
- LARS1 | c.3221C>T p.P1074L (on ENST00000394434 / NM_020117.11; = p.P1047L on NM_016460.3) | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs752258184, COSV50983357; called by muse, mutect2, varscan2
- LAT2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1554715690, COSV51922525; called by muse, mutect2, varscan2
- LEMD2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53395220; called by muse, mutect2, varscan2
- LGI2 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 60/205 reads (29%) | catalogued as COSV66123933; called by muse, mutect2, varscan2
- LGI3 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs531970563, COSV60443111, COSV60443347; called by muse, mutect2, varscan2
- LGR4 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV64866039; called by muse, mutect2, varscan2
- LGR5 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57009241, COSV57009381; called by muse, mutect2, varscan2
- LILRB4 | c.1241C>T p.A414V (on ENST00000391733 / NM_001278428.3; = p.A413V on NM_001278426.3) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54408288; called by muse, varscan2
- LIPE | c.237A>T p.Q79H | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as COSV54925139; called by muse, mutect2, varscan2
- LIPI | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.52); PolyPhen probably damaging (1); catalogued as COSV60715612; called by muse, mutect2, varscan2
- LPA | c.5846C>T p.T1949I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.875); catalogued as COSV60310403; called by muse, mutect2, varscan2
- LPO | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.075); catalogued as COSV51862036; called by muse, mutect2, varscan2
- LRIT2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV64519808; called by muse, mutect2, varscan2
- LRIT3 | c.956C>A p.S319Y | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59987448; called by muse, mutect2, varscan2
- LRRC34 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs762418016, COSV57187807; called by muse, mutect2, varscan2
- LRRC6 | c.293A>T p.N98I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51547061; called by muse, mutect2, varscan2
- LSG1 | c.585A>T p.E195D | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54572378; called by muse, mutect2, varscan2
- LSS | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.965); catalogued as COSV62702615; called by muse, mutect2, varscan2
- LTO1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV54163501; called by muse, mutect2, varscan2
- LUC7L2 | c.348T>A p.S116R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as COSV54929920, COSV54930256; called by muse, mutect2, varscan2
- LY75 | c.4075G>A p.D1359N | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55112198; called by muse, mutect2, varscan2
- LYPD5 | c.650C>T p.S217F (on ENST00000377950 / NM_001031749.3; = p.S174F on NM_182573.2) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs763874733, COSV65021235; called by muse, mutect2, varscan2
- LZTR1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.138); catalogued as rs1385691888, COSV53151285; called by muse, mutect2
- MAGI1 | c.3593G>C p.R1198P (on ENST00000402939 / NM_001033057.2; = p.R1227P on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV58322089, COSV58341870; called by muse, mutect2, varscan2
- MARCO | c.426G>A p.G142= | Splice Region (SNP) | VAF 37/112 reads (33%) | catalogued as COSV59054463; called by muse, mutect2, varscan2
- MARK2 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV59288594, COSV59289098; called by muse, mutect2, varscan2
- MARVELD3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV51705776; called by muse, mutect2, varscan2
- MAS1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.166); catalogued as COSV53122129; called by muse, mutect2, varscan2
- MB21D2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143060400; called by muse, mutect2, varscan2
- MDGA1 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51801072; called by muse, mutect2, varscan2
- MED12L | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746812746, COSV56394539; called by muse, mutect2, varscan2
- MGAM | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075200; called by muse, mutect2, varscan2
- MGAM | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs1554463881, COSV72075688; called by muse, mutect2, varscan2
- MROH5 | c.3633G>A p.W1211* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV61472730; called by muse, mutect2, varscan2
- MRTFB | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57961215; called by muse, mutect2, varscan2
- MTBP | c.1047G>A p.K349= | Splice Region (SNP) | VAF 59/199 reads (30%) | catalogued as COSV59966101; called by muse, mutect2, varscan2
- MTOR | c.7259C>T p.A2420V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63872793; called by muse, mutect2, varscan2
- MUC16 | c.38605G>A p.E12869K | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.365); catalogued as rs1196350883, COSV67484969; called by muse, mutect2, varscan2
- MUC16 | c.25054G>A p.A8352T | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.047); catalogued as COSV67455976, COSV67489604; called by muse, mutect2, varscan2
- MUC16 | c.19229C>T p.S6410F | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.271); catalogued as COSV67489606; called by muse, mutect2, varscan2
- MUC16 | c.4442C>T p.S1481L | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV67489615; called by muse, mutect2, varscan2
- MUC2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 112/385 reads (29%) | SIFT tolerated, low confidence (0.12); catalogued as rs1387901430; called by muse, mutect2, varscan2
- MUC6 | c.7069G>A p.E2357K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV59963734; called by muse, mutect2
- MUC7 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs750289514, COSV59218187; called by muse, mutect2, varscan2
- MX2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV58099101; called by muse, mutect2, varscan2
- MYH13 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as rs898339849, COSV52841049; called by muse, mutect2, varscan2
- MYH2 | c.5360G>A p.R1787Q | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs770182875, COSV55434133, COSV55439908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH4 | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV55125053; called by muse, mutect2, varscan2
- MYH6 | c.3978G>A p.K1326= | Splice Region (SNP) | VAF 28/118 reads (24%) | catalogued as COSV62448149, COSV62454023; called by muse, mutect2, varscan2
- MYO3A | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs779818103, COSV56346416; called by muse, mutect2, varscan2
- MYOM3 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV58400018; called by muse, mutect2, varscan2
- MYT1L | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.127); catalogued as COSV67731000; called by muse, mutect2, varscan2
- NAALADL1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60525722; called by muse, mutect2, varscan2
- NACA2 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 123/410 reads (30%) | catalogued as COSV71713100, COSV71713171; called by muse, mutect2, varscan2
- NAV3 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV57108526; called by muse, mutect2, varscan2
- NAV3 | c.7089A>T p.Q2363H (on ENST00000397909 / NM_001024383.2; = p.Q2341H on NM_014903.6) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57108541; called by muse, mutect2, varscan2
- NBEAL1 | c.5606A>G p.D1869G | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV71375386; called by muse, mutect2, varscan2
- NBEAL2 | c.6463C>T p.H2155Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52762447; called by muse, mutect2, varscan2
- NDST1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV104378823; called by muse, mutect2
- NEFH | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV60219804; called by muse, mutect2
- NEK11 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63579269, COSV63584287; called by muse, mutect2, varscan2
- NELL2 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs745705477, COSV61584131, COSV61584598; called by muse, mutect2, varscan2
- NETO1 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV55014478; called by muse, varscan2
- NFASC | c.1391+1G>T p.X464_splice (on ENST00000339876 / NM_001378329.1; = p.X475_splice on NM_015090.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100363406, COSV58378224; called by muse, mutect2, varscan2
- NLRC3 | c.2672C>A p.T891N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs752830420, COSV57095308; called by muse, mutect2
- NLRP11 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV64085946; called by muse, mutect2, varscan2
- NLRP11 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs866104256, COSV64086222; called by muse, mutect2, varscan2
- NLRP12 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs376225539, COSV60752662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54759640, COSV54759886; called by muse, mutect2, varscan2
- NME3 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV51602744; called by muse, mutect2, varscan2
- NOL4 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs764755868, COSV52357990; called by muse, mutect2, varscan2
- NOL6 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV53045289; called by muse, mutect2, varscan2
- NOTCH4 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1263014536, COSV66683484; called by muse, mutect2, varscan2
- NOX5 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs762413691, COSV52987118; called by muse, mutect2, varscan2
- NPBWR1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775911333, COSV100488281; called by muse, mutect2, varscan2
- NPR2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1217392431, COSV61310807; called by muse, mutect2, varscan2
- NPSR1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62196404; called by muse, mutect2, varscan2
- NRK | c.4150C>T p.P1384S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV54605416; called by muse, mutect2, varscan2
- NTRK1 | c.1319A>G p.N440S | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV62325422; called by muse, mutect2, varscan2
- NXF5 | n.1443-1G>A | Splice Site (SNP) | VAF 44/91 reads (48%) | catalogued as rs750005907, COSV99534603; called by muse, mutect2, varscan2
- OBSCN | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754019581, COSV52822012; called by muse, mutect2, varscan2
- OBSCN | c.8588G>A p.R2863K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.247); catalogued as rs1247389796, COSV52822042; called by muse, mutect2
- OCLN | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1280315953, COSV100783838; called by mutect2, varscan2
- OLFM3 | c.259C>T p.R87C (on ENST00000338858 / NM_001288821.1; = p.R67C on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1478170028, COSV58798851; called by muse, mutect2, varscan2
- OPCML | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59444670, COSV59446722; called by muse, mutect2, varscan2
- OR10J3 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867190348, COSV59955535; called by muse, varscan2
- OR10R2 | c.803T>G p.V268G | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63769450; called by muse, mutect2, varscan2
- OR1F1 | c.797A>C p.H266P | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58962269; called by muse, mutect2, varscan2
- OR1L1 | c.992C>T p.T331I (on ENST00000373686; = p.T281I on NM_001005236.3) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV58936585; called by muse, mutect2, varscan2
- OR2A5 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201237598; called by muse, mutect2
- OR2G3 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV60682959; called by muse, mutect2, varscan2
- OR2M3 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 113/583 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.395); catalogued as COSV71758826; called by muse, mutect2, varscan2
- OR2T33 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 136/304 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs778710122, COSV58815123; called by muse, varscan2
- OR2T8 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60662839, COSV60664665; called by muse, mutect2, varscan2
- OR3A3 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs747124017; called by muse, mutect2
- OR3A3 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52168463; called by muse, mutect2, varscan2
- OR4C46 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as COSV60221052; called by muse, mutect2, varscan2
- OR4K13 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV59859801; called by muse, mutect2, varscan2
- OR4K14 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV59294066; called by muse, mutect2, varscan2
- OR51B5 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56177177; called by muse, mutect2, varscan2
- OR51I1 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs772513140, COSV66507109; called by muse, mutect2, varscan2
- OR52E4 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57625997; called by muse, mutect2, varscan2
- OR52J3 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100984955, COSV66747705; called by muse, mutect2, varscan2
- OR52N5 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57699436; called by muse, mutect2, varscan2
- OR5AP2 | c.773T>A p.F258Y | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.34); catalogued as COSV57258674; called by muse, mutect2, varscan2
- OR5AR1 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs767339924, COSV57255214; called by muse, mutect2, varscan2
- OR5M10 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV73242433; called by muse, mutect2, varscan2
- OR5V1 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV65830045; called by muse, mutect2, varscan2
- OR6C4 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 46/180 reads (26%) | catalogued as COSV67793259; called by muse, mutect2, varscan2
- OR6C70 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs767288966, COSV59244972; called by muse, mutect2, varscan2
- OR8D4 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs150490501, COSV58431392; called by muse, mutect2, varscan2
- OR8K3 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.356); catalogued as COSV57132864; called by muse, mutect2, varscan2
- PACSIN1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.34); catalogued as rs373593502; called by muse, mutect2, varscan2
- PALLD | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54993029; called by muse, mutect2, varscan2
- PAM | c.2666G>A p.W889* | Nonsense Mutation (SNP) | VAF 40/129 reads (31%) | catalogued as COSV57219081; called by muse, mutect2, varscan2
- PARP12 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 83/257 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV54936788; called by muse, mutect2, varscan2
- PAX4 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV58391086; called by muse, mutect2, varscan2
- PCDH15 | c.3984-1G>A p.X1328_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV57301113, COSV57303763; called by muse, mutect2
- PCDHA2 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.027); catalogued as COSV65370681; called by muse, mutect2, varscan2
- PCDHA4 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as rs1311531851, COSV63545521, COSV63546348; called by muse, mutect2, varscan2
- PCDHA7 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.172); catalogued as COSV65342304; called by muse, mutect2, varscan2
- PCDHB11 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100697144; called by muse, mutect2, varscan2
- PCDHB6 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV50694999, COSV99170729; called by muse, mutect2, varscan2
- PCDHGA1 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV65299100; called by muse, mutect2, varscan2
- PCDHGC4 | c.2068A>G p.T690A | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753291480, COSV99341892; called by muse, mutect2, varscan2
- PCLO | c.8896C>T p.R2966C | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173009964, COSV61649863; called by muse, mutect2, varscan2
- PCSK1 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60737288; called by muse, mutect2, varscan2
- PDGFC | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.437); catalogued as COSV56854143; called by muse, mutect2, varscan2
- PDGFRA | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.061); catalogued as COSV57273187; called by muse, mutect2, varscan2
- PDGFRA | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57273191; called by muse, mutect2, varscan2
- PEAR1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52775571; called by muse, mutect2, varscan2
- PHF14 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as rs775864794, COSV68854898; called by muse, mutect2, varscan2
- PIEZO2 | c.6805G>A p.G2269R | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760201421, COSV53293449; called by muse, mutect2, varscan2
- PITPNM2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV54907747; called by muse, mutect2, varscan2
- PKD1 | c.12800G>A p.R4267Q (on ENST00000262304 / NM_001009944.3; = p.R4266Q on NM_000296.4) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs771965935, COSV51919340; called by muse, mutect2, varscan2
- PKD1L1 | c.4984T>A p.L1662I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.813); catalogued as COSV99221084; called by muse, mutect2, varscan2
- PKDREJ | c.4670C>T p.S1557F | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.233); catalogued as COSV53552626; called by muse, mutect2, varscan2
- PLA2G4E | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370317501; called by muse, mutect2, varscan2
- PLA2R1 | c.4199C>T p.P1400L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV51785679; called by muse, mutect2, varscan2
- PLCZ1 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV56858016; called by muse, varscan2
- PLCZ1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs779427460, COSV56848630; called by muse, varscan2
- PLEKHG3 | c.407C>T p.A136V (on ENST00000394691; = p.A192V on NM_001308147.2) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs761963034, COSV55983504; called by muse, mutect2, varscan2
- PLSCR4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV61608946; called by muse, mutect2, varscan2
- PMFBP1 | c.3020C>T p.P1007L (on ENST00000537465; = p.P1002L on NM_031293.3) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as rs559237924, COSV52831067; called by muse, mutect2, varscan2
- PMS2 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56151872; called by muse, mutect2
- POLN | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV67027352; called by muse, mutect2, varscan2
- POLR3E | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV55399631; called by muse, mutect2, varscan2
- POM121C | c.1751C>T p.P584L (on ENST00000607367; = p.P342L on NM_001099415.3) | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV57548911; called by muse, mutect2, varscan2
- POSTN | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65714428; called by muse, mutect2, varscan2
- PPP1R14C | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.569); catalogued as COSV63174108; called by muse, mutect2, varscan2
- PPP6R3 | c.1152G>A p.W384* (on ENST00000393800 / NM_001352375.2; = p.W333* on NM_018312.5) | Nonsense Mutation (SNP) | VAF 71/119 reads (60%) | catalogued as COSV55735109; called by muse, mutect2, varscan2
- PRDM14 | c.1186T>G p.S396A | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.1); catalogued as COSV52575113; called by muse, mutect2, varscan2
- PREP | c.413C>T p.T138I (on ENST00000369110; = p.T204I on NM_002726.5) | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV64871903; called by muse, mutect2, varscan2
- PROM2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.258); catalogued as COSV58300484; called by muse, mutect2, varscan2
- PRR35 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV50319960; called by muse, mutect2, varscan2
- PRRG3 | c.168G>A p.T56= | Splice Region (SNP) | VAF 26/60 reads (43%) | catalogued as rs1350244900, COSV64851461; called by muse, mutect2, varscan2
- PRSS23 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs773274738, COSV54707574; called by muse, mutect2, varscan2
- PSMC1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54321982; called by muse, mutect2, varscan2
- PTPN20 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 75/423 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV55889233; called by muse, mutect2, varscan2
- PTPN22 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63086349, COSV63086395; called by muse, mutect2, varscan2
- PTPRB | c.4564C>T p.R1522W | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs759754918, COSV54238534; called by muse, mutect2, varscan2
- PTPRD | c.2864C>T p.T955I | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs763256154, COSV61977473, COSV61980890; called by muse, mutect2, varscan2
- PTPRT | c.1645A>T p.T549S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.633); catalogued as COSV62013797; called by muse, mutect2, varscan2
- PUM2 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV57584830; called by muse, mutect2, varscan2
- PYGM | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1360941286, COSV51225896; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV51487903; called by muse, mutect2, varscan2
- RAD51AP2 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV67588007, COSV67589066; called by muse, mutect2, varscan2
- RCSD1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs182067342, COSV63260800; called by muse, mutect2, varscan2
- RDH16 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV62458708; called by muse, mutect2, varscan2
- REC114 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 70/269 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58524457; called by muse, mutect2, varscan2
- REN | c.493-1G>A p.X165_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | catalogued as COSV65818340, COSV99689486; called by muse, mutect2, varscan2
- RFX4 | c.1360C>T p.H454Y (on ENST00000392842 / NM_213594.3; = p.H360Y on NM_032491.6) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV57580630; called by muse, mutect2, varscan2
- RGS22 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV62666856; called by muse, mutect2, varscan2
- RHBDD1 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58131061; called by muse, mutect2, varscan2
- RNF180 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.1); catalogued as COSV56964716; called by muse, mutect2, varscan2
- RNF34 | c.927C>T p.S309= | Splice Region (SNP) | VAF 26/106 reads (25%) | catalogued as COSV63441965, COSV63443351; called by muse, mutect2, varscan2
- RNF43 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 34/152 reads (22%) | catalogued as COSV68457127; called by muse, mutect2, varscan2
- ROS1 | c.6886G>A p.E2296K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs761155034, COSV63857239; called by muse, mutect2, varscan2
- RP1 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV55124723; called by muse, mutect2, varscan2
- RP1 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV55113016; called by muse, mutect2, varscan2
- RP1 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs866399055, COSV55111239; called by muse, mutect2, varscan2
- RPL18A | c.68A>C p.H23P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55830762; called by muse, mutect2, varscan2
- RPS6KL1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs769386703, COSV63581787; called by muse, mutect2, varscan2
- RPTN | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 182/662 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV60167498; called by muse, mutect2, varscan2
- RYR1 | c.2321G>A p.G774E | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62089802; called by muse, mutect2, varscan2
- SACS | c.10173C>A p.F3391L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.97); catalogued as COSV66546154; called by muse, mutect2, varscan2
- SAMD4A | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867732128, COSV51878150; called by muse, mutect2, varscan2
- SAMD9L | c.3167C>T p.S1056F | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs867461861, COSV59080983; called by muse, mutect2, varscan2
- SASH1 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs139892427; called by muse, mutect2, varscan2
- SBF1 | c.2372C>G p.A791G | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.269); catalogued as COSV62370184; called by muse, mutect2, varscan2
- SCAF8 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1272395095, COSV65792671; called by muse, mutect2, varscan2
- SCAPER | c.2950C>T p.P984S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV57751928; called by muse, mutect2, varscan2
- SCLY | c.1210C>T p.P404S (on ENST00000651534; = p.P396S on NM_016510.7) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV54543922; called by muse, mutect2
- SCN2A | c.5198C>T p.P1733L | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV51853649, COSV99332200; called by muse, mutect2, varscan2
- SCN3A | c.1835T>A p.F612Y | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV51822316; called by muse, mutect2, varscan2
- SCN5A | c.6025G>A p.D2009N (on ENST00000333535 / NM_198056.3; = p.D2008N on NM_000335.5) | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV61139140; called by muse, mutect2, varscan2
- SCYL1 | c.696C>T p.I232= | Splice Region (SNP) | VAF 8/49 reads (16%) | catalogued as COSV54215460; called by muse, mutect2, varscan2
- SECISBP2L | c.1298C>T p.P433L (on ENST00000559471 / NM_001193489.2; = p.P388L on NM_014701.4) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55937421; called by muse, mutect2, varscan2
- SEL1L2 | c.1835G>A p.R612K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV53157328; called by muse, mutect2, varscan2
- SELP | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 57/197 reads (29%) | catalogued as COSV55257811; called by muse, varscan2
- SELP | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV55251719; called by muse, varscan2
- SEMA3D | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52402998; called by muse, mutect2, varscan2
- SERPINA1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63345420; called by muse, mutect2, varscan2
- SERPINA10 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV100003991; called by muse, mutect2, varscan2
- SHLD1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs749622214, COSV57439192; called by muse, mutect2, varscan2
- SI | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52287827; called by muse, mutect2, varscan2
- SIGLEC1 | c.1912C>T p.H638Y | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52471512, COSV99165015; called by muse, mutect2, varscan2
- SIGLEC6 | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV58432899; called by muse, mutect2, varscan2
- SIRT3 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as rs1365031210, COSV61501771; called by muse, mutect2, varscan2
- SLC12A6 | c.1487T>G p.V496G (on ENST00000354181 / NM_001365088.1; = p.V445G on NM_005135.2) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV51631103; called by muse, mutect2, varscan2
- SLC15A2 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55197358; called by muse, mutect2
- SLC16A9 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV68100445; called by muse, mutect2, varscan2
- SLC17A6 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54140615; called by muse, mutect2, varscan2
- SLC18A2 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53693280; called by muse, mutect2, varscan2
- SLC19A2 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV52548628, COSV52548902; called by muse, mutect2, varscan2
- SLC25A11 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468466553, COSV52591984; called by muse, mutect2, varscan2
- SLC25A52 | c.616C>T p.P206S (on ENST00000672005; = p.P196S on NM_001034172.4) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV52504216; called by muse, mutect2, varscan2
- SLC30A6 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.207); catalogued as COSV50874248, COSV99249344; called by muse, mutect2, varscan2
- SLC38A5 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as COSV58335440; called by muse, mutect2, varscan2
- SLC4A3 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV56097102; called by muse, mutect2, varscan2
- SLC4A3 | c.495+1G>A p.X165_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56097109; called by muse, mutect2, varscan2
- SLC4A7 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868671813, COSV55402117; called by muse, mutect2, varscan2
- SLC9C1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs779690767, COSV59885462; called by muse, mutect2, varscan2
- SLITRK3 | c.1387C>T p.L463F | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53852792; called by muse, mutect2, varscan2
- SMARCA2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61811957; called by muse, mutect2, varscan2
- SMARCC2 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV57224202; called by muse, mutect2, varscan2
- SNCAIP | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775708743, COSV54420188; called by muse, mutect2, varscan2
- SPAG17 | c.5141T>G p.L1714R | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60467182; called by muse, mutect2, varscan2
- SPHKAP | c.4942G>A p.E1648K (on ENST00000392056 / NM_001142644.2; = p.E1619K on NM_030623.3) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1168622403, COSV60892198; called by muse, mutect2, varscan2
- SPHKAP | c.2774G>A p.C925Y | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV60892213; called by muse, mutect2, varscan2
- SPRR2E | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as COSV64203973; called by muse, mutect2, varscan2
- SPTB | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750069570, COSV67634724; called by muse, mutect2
- SRPX2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.079); catalogued as COSV65934455; called by muse, varscan2
- ST18 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV99390783; called by muse, mutect2, varscan2
- STAB2 | c.3680C>T p.S1227F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66345890; called by muse, mutect2, varscan2
- STEAP2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV55293426; called by muse, mutect2, varscan2
- STEAP3 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.129); catalogued as rs1422601380, COSV61530848; called by muse, mutect2, varscan2
- STK10 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV51578371; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs148943401; called by muse, mutect2, varscan2
- SUMF1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV55994880, COSV55995650; called by muse, mutect2, varscan2
- SYCP1 | c.2464C>T p.R822* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as COSV65700583; called by muse, mutect2, varscan2
- SYT16 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); catalogued as COSV70859447; called by muse, varscan2
- SYT16 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs1409503101, COSV70859455; called by muse, varscan2
- TACC2 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs200691895, COSV57770863; called by muse, mutect2, varscan2
- TAFA4 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138970524; called by muse, mutect2, varscan2
- TAS2R14 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV67862055; called by muse, mutect2, varscan2
- TAS2R38 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV71885993; called by muse, mutect2, varscan2
- TBC1D1 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV54726176; called by muse, mutect2, varscan2
- TCIM | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370896349; called by muse, mutect2, varscan2
- TECRL | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868813288, COSV67086762; called by muse, mutect2, varscan2
- TENT5B | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56693849; called by muse, mutect2, varscan2
- TET2 | c.1463A>G p.N488S | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs758328975, COSV54430565; called by muse, mutect2, varscan2
- TEX15 | c.4543C>T p.H1515Y (on ENST00000256246; = p.H1898Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as COSV56352724; called by muse, mutect2, varscan2
- THSD7B | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as rs747686362, COSV55665973, COSV55731772; called by muse, mutect2, varscan2
- TIMELESS | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1391908990, COSV57514778; called by muse, mutect2, varscan2
- TMEM132B | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54767579; called by muse, mutect2, varscan2
- TMEM74 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52464586; called by muse, mutect2, varscan2
- TNK2 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57375008; called by muse, mutect2, varscan2
- TPP1 | c.490G>C p.A164P | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV54995199; called by muse, mutect2, varscan2
- TPTE | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as rs1302263000; called by muse, mutect2, varscan2
- TRIM49 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.173); catalogued as COSV61672560; called by muse, mutect2, varscan2
- TRIM55 | c.353A>T p.K118I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV52550139; called by muse, mutect2, varscan2
- TSGA10IP | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as COSV73245371; called by muse, mutect2, varscan2
- TSHZ3 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53672115, COSV53678473; called by muse, mutect2, varscan2
- TSPAN12 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV56081651; called by muse, mutect2, varscan2
- TTN | c.36169G>A p.E12057K (on ENST00000591111; = p.E4633K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | PolyPhen probably damaging (0.994); catalogued as COSV60303750; called by muse, mutect2, varscan2
- TTN | c.17482G>A p.E5828K (on ENST00000591111; = p.E4901K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | PolyPhen possibly damaging (0.54); catalogued as rs267599065, COSV60006328; called by muse, varscan2
- TTN | c.12808G>A p.E4270K (on ENST00000591111; = p.E4224K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV60035489; called by muse, mutect2, varscan2
- TXK | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.156); catalogued as COSV51919247; called by muse, mutect2, varscan2
- UBE2U | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as rs751395768, COSV64281244, COSV64281638; called by muse, mutect2, varscan2
- UBR1 | c.4277C>T p.P1426L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as CM1111774, COSV51935690; called by muse, mutect2, varscan2
- UGT1A6 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59396945; called by muse, mutect2, varscan2
- ULBP2 | c.510A>T p.E170D | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV66265131, COSV66265922; called by muse, mutect2, varscan2
- UQCRC1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1306228462, COSV52552920; called by muse, mutect2, varscan2
- USP28 | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV50158265; called by muse, mutect2, varscan2
- UTRN | c.4947C>T p.N1649= | Splice Region (SNP) | VAF 21/76 reads (28%) | catalogued as COSV62332388; called by muse, mutect2, varscan2
- VPS13A | c.1596-1G>A p.X532_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as CS022684, COSV62437723; called by muse, mutect2, varscan2
- VSIG10 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs752624021, COSV63654335; called by muse, mutect2, varscan2
- WDR24 | c.1508G>A p.R503Q (on ENST00000248142; = p.R373Q on NM_032259.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.347); catalogued as rs776909405, COSV50203590; called by muse, mutect2, varscan2
- WDR90 | c.4570C>T p.H1524Y | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs376132942, COSV99554064; called by muse, mutect2, varscan2
- XIRP2 | c.1966G>A p.E656K (on ENST00000628543; = p.E831K on NM_152381.6) | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54679776, COSV99748346; called by muse, mutect2, varscan2
- XIRP2 | c.8269G>A p.E2757K (on ENST00000628543; = p.E2932K on NM_152381.6) | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV54713242; called by muse, mutect2, varscan2
- XKR3 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.078); catalogued as rs760369835, COSV58887806; called by muse, mutect2, varscan2
- XKR4 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771115839, COSV59318340; called by muse, mutect2, varscan2
- ZACN | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); catalogued as rs971667291, COSV58035596; called by muse, mutect2, varscan2
- ZFHX4 | c.5065C>T p.Q1689* | Nonsense Mutation (SNP) | VAF 31/124 reads (25%) | catalogued as COSV50500579, COSV51492416; called by muse, mutect2, varscan2
- ZFP64 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53803392; called by muse, mutect2, varscan2
- ZNF157 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV65659691; called by muse, mutect2, varscan2
- ZNF223 | c.1371A>T p.K457N | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV69691622; called by muse, mutect2, varscan2
- ZNF239 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60019590; called by muse, mutect2, varscan2
- ZNF334 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV61619960; called by muse, mutect2, varscan2
- ZNF493 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV62751796; called by muse, mutect2, varscan2
- ZNF544 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV54138260; called by muse, mutect2, varscan2
- ZNF572 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV60002706; called by muse, mutect2, varscan2
- ZNF599 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV61397336; called by muse, mutect2, varscan2
- ZNF627 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV63142806; called by muse, mutect2, varscan2
- ZNF644 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 53/204 reads (26%) | catalogued as COSV61350088; called by muse, mutect2, varscan2
- ZNF648 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV60572570; called by muse, mutect2, varscan2
- ZNF816 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54412360; called by muse, mutect2, varscan2
- ZNF831 | c.2945C>T p.S982L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs1277301009, COSV64044656; called by muse, mutect2, varscan2
- ZSCAN4 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV58999394; called by muse, mutect2, varscan2
- ZSCAN5B | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1163381663, COSV61999301; called by muse, mutect2, varscan2
- C17orf98 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CYB5B | c.362+1_362+5del p.X121_splice | Splice Site (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel, varscan2
- EXPH5 | c.901_905del p.R301Afs*5 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- FAM216B | c.362_376del p.P121_V125del | In Frame Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- KDSR | c.567dup p.K190Qfs*19 | Frame Shift Ins (INS) | VAF 59/210 reads (28%) | called by mutect2, pindel, varscan2
- PPIAL4A | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TADA2A | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- WNK2 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ABCC10 | c.3399C>A p.L1133= (on ENST00000372530 / NM_001198934.2; = p.L1105= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as COSV55093418; called by muse, mutect2, varscan2
- ABCC8 | c.4509C>T p.I1503= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV56856702, COSV56856855; called by muse, mutect2, varscan2
- ABCC8 | c.1545G>A p.E515= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV56856712; called by muse, mutect2, varscan2
- ACSM2A | c.318G>A p.G106= (on ENST00000219054; = p.G27= on NM_001308169.2) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1567361996, COSV54588950; called by muse, mutect2, varscan2
- ADAM2 | c.636G>A p.T212= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs187181948, COSV55867570; called by muse, mutect2, varscan2
- ADAMTS12 | c.408C>T p.A136= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs375731869, COSV100711553; called by muse, mutect2, varscan2
- ADAMTS6 | c.756G>A p.V252= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV66864048; called by muse, mutect2, varscan2
- ADARB2 | c.1662C>T p.S554= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs765790012, COSV67235133; called by muse, mutect2, varscan2
- ADGRA2 | c.1752C>T p.P584= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs763323256, COSV100177854, COSV59445862; called by muse, mutect2, varscan2
- ADGRB1 | c.3852C>T p.S1284= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1282169393, COSV60102785; called by muse, mutect2, varscan2
- ANK3 | c.1911C>T p.I637= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as rs539885495, COSV55078786; called by muse, mutect2, varscan2
- ANO4 | c.1842C>T p.F614= (on ENST00000392977 / NM_001286615.2; = p.F579= on NM_178826.4) | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs1433234975, COSV100153566; called by muse, mutect2, varscan2
- AQP12B | c.111C>T p.F37= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs369678598; called by muse, mutect2, varscan2
- ARHGEF12 | c.1995C>T p.S665= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100755159; called by muse, mutect2, varscan2
- ARHGEF17 | c.3558C>T p.L1186= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV55235880, COSV55237296; called by muse, mutect2, varscan2
- ATAD3B | c.726C>T p.I242= (on ENST00000308647; = p.I348= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV58023053; called by muse, mutect2, varscan2
- ATP11C | c.2058C>T p.S686= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV59572843; called by muse, mutect2, varscan2
- ATP13A4 | c.2457C>T p.T819= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV61326212; called by muse, mutect2, varscan2
- ATP13A5 | c.3273C>T p.F1091= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV60874581; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2406C>T p.F802= | Silent (SNP) | VAF 58/254 reads (23%) | catalogued as rs774637198, COSV59479730; called by muse, mutect2, varscan2
- ATP8B2 | c.3285C>T p.A1095= (on ENST00000672630; = p.A1062= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV63833558; called by muse, mutect2, varscan2
- B3GAT1 | c.579C>T p.F193= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs765229137, COSV56995948; called by muse, mutect2, varscan2
- BAG4 | c.498C>T p.S166= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV54862186; called by muse, mutect2, varscan2
- BAHCC1 | c.1705C>T p.L569= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV57032615; called by muse, mutect2, varscan2
- BCOR | c.1542A>G p.P514= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV60716755; called by muse, mutect2, varscan2
- BCORL1 | c.4167C>T p.V1389= | Silent (SNP) | VAF 75/175 reads (43%) | catalogued as rs780143502, COSV54405713; called by muse, mutect2, varscan2
- BPI | c.117G>A p.R39= (on ENST00000262865; = p.R35= on NM_001725.3) | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV53408067; called by muse, mutect2, varscan2
- BRD4 | c.675C>T p.F225= | Silent (SNP) | VAF 62/210 reads (30%) | catalogued as rs200115372, COSV54593856; called by muse, mutect2, varscan2
- BRD9 | c.1341C>T p.I447= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1479875416, COSV60249669; called by muse, mutect2, varscan2
- BRD9 | c.1152C>T p.S384= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as rs1294068809, COSV60249688; called by muse, mutect2
- BRF2 | c.933C>T p.A311= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV55105387; called by muse, mutect2, varscan2
- BTN1A1 | c.1008G>A p.E336= | Silent (SNP) | VAF 56/198 reads (28%) | catalogued as rs1165762504, COSV55069448, COSV99764432; called by muse, mutect2, varscan2
- C12orf4 | c.1278C>T p.I426= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV54209352; called by muse, mutect2, varscan2
- C4BPB | c.681G>A p.K227= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV54691897; called by muse, mutect2, varscan2
- C8B | c.624G>A p.T208= | Silent (SNP) | VAF 50/196 reads (26%) | catalogued as rs148088012; called by muse, mutect2, varscan2
- CABS1 | c.1116G>A p.K372= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV56734399; called by muse, mutect2, varscan2
- CACNA1C | c.1998C>T p.S666= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV59698355; called by muse, mutect2, varscan2
- CALR3 | c.264G>A p.G88= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as COSV54171870; called by muse, mutect2, varscan2
- CAMTA1 | c.540G>A p.L180= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs774544631, COSV57923428; called by muse, mutect2, varscan2
- CATSPERB | c.421C>T p.L141= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV56433836; called by muse, mutect2, varscan2
- CCDC105 | c.1095G>A p.T365= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV52963179; called by muse, mutect2, varscan2
- CCDC170 | c.981G>A p.R327= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV53345696; called by muse, mutect2, varscan2
- CCDC30 | c.2358G>A p.K786= (on ENST00000340612; = p.K743= on NM_001080850.3) | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV59246504; called by muse, mutect2, varscan2
- CCNA1 | c.525C>T p.F175= | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as COSV55223717; called by muse, mutect2, varscan2
- CCNB3 | c.2673C>T p.I891= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV52079033; called by muse, mutect2, varscan2
- CDC42BPG | c.4134C>T p.L1378= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV61348991; called by muse, mutect2, varscan2
- CDH17 | c.471C>T p.A157= | Silent (SNP) | VAF 65/247 reads (26%) | catalogued as COSV50338889; called by muse, mutect2, varscan2
- CDH8 | c.1488C>T p.F496= | Silent (SNP) | VAF 52/173 reads (30%) | catalogued as rs770747257, COSV54859142, COSV54882508; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1402C>T p.L468= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV58116013; called by muse, mutect2, varscan2
- CEACAM19 | c.21C>T p.T7= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1479207019, COSV62552280; called by muse, mutect2, varscan2
- CHAT | c.999G>A p.L333= | Silent (SNP) | VAF 56/196 reads (29%) | catalogued as COSV60319406, COSV60332083; called by muse, mutect2, varscan2
- CHRFAM7A | c.186C>T p.I62= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs752516895, COSV55397190; called by mutect2, varscan2
- CIB4 | c.432G>A p.T144= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs370261225; called by muse, mutect2, varscan2
- CILP | c.3070C>T p.L1024= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV56027539; called by muse, mutect2, varscan2
- CIZ1 | c.855C>T p.A285= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV52974251; called by muse, mutect2, varscan2
- CLDN1 | c.459C>T p.T153= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV55045069; called by muse, mutect2, varscan2
- CLEC4F | c.111C>T p.L37= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs782592563, COSV55478162; called by muse, mutect2, varscan2
- COL5A3 | c.3351C>T p.D1117= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs199836827, COSV53418183; called by muse, mutect2, varscan2
- COLQ | c.1287C>T p.T429= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV67525841; called by muse, mutect2, varscan2
- CUX2 | c.3609C>T p.F1203= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV55645966; called by muse, mutect2, varscan2
- CXXC5 | c.222C>T p.R74= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs746631038, COSV56795705; called by muse, mutect2, varscan2
- CYP4F11 | c.1563G>A p.A521= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1296561213, COSV56125770; called by muse, mutect2, varscan2
- DAGLA | c.2751C>T p.I917= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1051782947, COSV57199286; called by muse, mutect2, varscan2
- DENND5B | c.3040A>C p.R1014= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100172016; called by muse, mutect2, varscan2
- DENND5B | c.3039C>T p.V1013= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100172017; called by muse, mutect2, varscan2
- DEPDC7 | c.1056C>T p.F352= (on ENST00000241051 / NM_001077242.2; = p.F343= on NM_139160.2) | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as COSV53809113; called by muse, mutect2, varscan2
- DMXL2 | c.7593G>A p.L2531= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV51854803; called by muse, mutect2, varscan2
- DNAH3 | c.5478C>T p.S1826= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1567660810, COSV54547457; called by muse, mutect2, varscan2
- DNAH5 | c.11937G>A p.E3979= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV54248346; called by muse, mutect2, varscan2
- DNAH5 | c.2865C>T p.A955= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV54248396; called by muse, mutect2, varscan2
- DNAH7 | c.8601C>T p.D2867= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV56782846; called by muse, mutect2, varscan2
- DNAH7 | c.2013G>A p.R671= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs373012562; called by muse, mutect2, varscan2
- DPY19L4 | c.1143C>T p.F381= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1043693385, COSV68963658; called by muse, mutect2, varscan2
- DRD1 | c.1149G>A p.K383= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs756834255, COSV101192547, COSV67105166; called by muse, mutect2, varscan2
- DRD5 | c.1029C>T p.V343= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs1490061045, COSV58580117; called by muse, mutect2, varscan2
- DRG2 | c.684C>T p.F228= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV56729369; called by muse, mutect2, varscan2
- DUOX2 | c.4374C>T p.F1458= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs1233860533, COSV66530594, COSV66531742; called by muse, mutect2, varscan2
- ELMOD3 | c.369C>T p.I123= | Silent (SNP) | VAF 75/256 reads (29%) | catalogued as COSV59772322; called by muse, mutect2, varscan2
- EPPK1 | c.1788G>A p.V596= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV101599938; called by muse, mutect2, varscan2
- EPS8L3 | c.165C>T p.F55= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as rs1451563967, COSV62610441; called by muse, mutect2, varscan2
- ERI2 | c.669C>T p.A223= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV55503794; called by muse, mutect2, varscan2
- ERN2 | c.1173G>A p.E391= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as rs1472595641, COSV56837512; called by muse, mutect2, varscan2
- ETV3L | c.490C>T p.L164= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV71901196; called by muse, mutect2, varscan2
- EXOC4 | c.591C>T p.H197= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs1563010962, COSV54119598; called by muse, mutect2, varscan2
- F2RL1 | c.231C>T p.F77= | Silent (SNP) | VAF 51/224 reads (23%) | catalogued as COSV56996172; called by muse, mutect2, varscan2
- FAM117B | c.1266C>T p.S422= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV57421777; called by muse, mutect2, varscan2
- FAM135B | c.2229C>T p.I743= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs1338500603, COSV52749985; called by muse, mutect2, varscan2
- FAM47A | c.1590C>T p.L530= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs867596772, COSV60494472; called by muse, varscan2
- FAM47B | c.1275G>A p.P425= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs1343349349, COSV100264156, COSV61455837; called by muse, mutect2, varscan2
- FAT3 | c.3159G>A p.K1053= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as COSV53165962; called by muse, mutect2, varscan2
- FAT3 | c.6306G>A p.L2102= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV53166000; called by muse, mutect2, varscan2
- FHL3 | c.39C>T p.S13= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs1290318175, COSV65952643; called by muse, mutect2, varscan2
- FILIP1 | c.2337C>T p.S779= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as COSV52739454; called by muse, mutect2, varscan2
- FLT1 | c.255C>G p.G85= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as COSV56740931; called by muse, mutect2, varscan2
- FPR2 | c.957C>T p.T319= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as rs748143573, COSV60674283; called by muse, mutect2, varscan2
- FRMD1 | c.438C>T p.Y146= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs572609253, COSV51960001; called by muse, mutect2, varscan2
- FRMPD2 | c.3798G>A p.R1266= | Silent (SNP) | VAF 43/142 reads (30%) | called by mutect2, varscan2
- FSTL5 | c.945C>T p.H315= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs750819805, COSV60180662; called by muse, mutect2, varscan2
- GABRG3 | c.327C>T p.F109= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV61510413; called by muse, mutect2, varscan2
- GALNT14 | c.1527C>T p.I509= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs565883379, COSV61110416; called by muse, mutect2, varscan2
- GALNT5 | c.2304C>T p.I768= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs776944776, COSV52040777; called by muse, mutect2, varscan2
- GIMAP6 | c.630C>T p.A210= | Silent (SNP) | VAF 65/260 reads (25%) | catalogued as COSV61034415; called by muse, mutect2, varscan2
- GPR75 | c.1056C>T p.F352= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV61831790, COSV61833438; called by muse, mutect2, varscan2
- GRIP1 | c.336C>T p.F112= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as COSV54039879; called by muse, mutect2, varscan2
- GRM7 | c.1338G>A p.K446= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV63166899, COSV63178718; called by muse, varscan2
- GSK3B | c.516C>T p.I172= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV51781850; called by muse, mutect2, varscan2
- HAUS8 | c.894G>A p.K298= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as COSV53727288; called by muse, mutect2, varscan2
- HEATR1 | c.3969C>T p.I1323= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV63979938, COSV63982852; called by muse, mutect2, varscan2
- HIF3A | c.1386C>T p.L462= (on ENST00000377670 / NM_152795.4; = p.L393= on NM_022462.4) | Silent (SNP) | VAF 34/182 reads (19%) | catalogued as COSV52203793; called by muse, mutect2, varscan2
- HPS1 | c.2025C>T p.I675= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV57270111; called by muse, mutect2, varscan2
- HS3ST1 | c.621C>T p.F207= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs139094851, COSV50023676; called by muse, mutect2, varscan2
- HS3ST1 | c.72G>A p.E24= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV50026115; called by muse, mutect2, varscan2
- HS3ST2 | c.339G>A p.R113= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1348652391, COSV54467955; called by muse, mutect2, varscan2
- IFT57 | c.867C>T p.L289= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV52712153; called by muse, mutect2, varscan2
- INSRR | c.3504C>T p.I1168= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs866669566, COSV63876845; called by muse, mutect2, varscan2
- IQUB | c.1134G>A p.R378= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV61242353; called by muse, mutect2, varscan2
- ITGA4 | c.87G>A p.P29= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs374263102; called by muse, mutect2, varscan2
- ITGA4 | c.1446G>A p.T482= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as rs1356750924, COSV51998194; called by muse, mutect2, varscan2
- ITGB4 | c.3300C>T p.I1100= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2
- KATNAL2 | c.564C>T p.D188= (on ENST00000356157 / NM_001353899.1; = p.D116= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV55307548; called by muse, mutect2
- KCNB2 | c.1275G>A p.K425= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV73048996, COSV73049582; called by muse, mutect2, varscan2
- KDM7A | c.981C>T p.F327= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV50095409; called by muse, mutect2, varscan2
- KRT23 | c.1050G>A p.Q350= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV52928866; called by muse, mutect2, varscan2
- LAMA3 | c.759C>T p.T253= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV58078588; called by muse, mutect2, varscan2
- LAMA3 | c.8037C>T p.D2679= (on ENST00000313654 / NM_198129.4; = p.D1070= on NM_000227.6) | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs1204799104, COSV52542298; called by muse, mutect2, varscan2
- LAMA5 | c.10008C>T p.T3336= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53370988; called by muse, mutect2, varscan2
- LAMA5 | c.4284C>T p.S1428= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV53370998; called by muse, mutect2, varscan2
- LMO7 | c.4365C>T p.I1455= (on ENST00000357063; = p.I1136= on NM_005358.5) | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV58547196; called by muse, mutect2, varscan2
- LRP12 | c.672C>T p.S224= | Silent (SNP) | VAF 42/143 reads (29%) | catalogued as COSV52633958; called by muse, mutect2, varscan2
- LRRC1 | c.384G>A p.Q128= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100905989, COSV63825092; called by muse, mutect2, varscan2
- LRRC7 | c.1587G>A p.G529= (on ENST00000651989 / NM_001370785.2; = p.G496= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV50606488; called by muse, mutect2, varscan2
- LTBP3 | c.1563G>A p.E521= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV57242184, COSV57243724; called by muse, mutect2, varscan2
- MAGEC1 | c.1857G>A p.E619= | Silent (SNP) | VAF 131/336 reads (39%) | catalogued as COSV53578991, COSV53580208; called by muse, mutect2, varscan2
- MAP3K21 | c.876G>A p.L292= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV64046365, COSV64047201; called by muse, mutect2, varscan2
- MCTP2 | c.180C>T p.A60= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV59149640; called by muse, mutect2, varscan2
- METTL4 | c.265C>A p.R89= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV55249569, COSV99859518; called by muse, mutect2, varscan2
- MFSD1 | c.1218C>T p.I406= | Silent (SNP) | VAF 134/504 reads (27%) | catalogued as COSV51841961; called by muse, mutect2, varscan2
- MGAM | c.5286G>A p.G1762= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs745786997, COSV72073721, COSV72075224; called by muse, mutect2, varscan2
- MROH2B | c.2076G>A p.G692= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs754225587, COSV68188476; called by muse, mutect2
- MSLN | c.732G>A p.T244= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs766340711, COSV53499855; called by muse, mutect2
- MTMR12 | c.2061C>T p.A687= | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as rs1415678172, COSV53787543; called by muse, mutect2, varscan2
- MUC16 | c.27426C>T p.S9142= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1467331829, COSV67484989; called by muse, mutect2, varscan2
- MUC16 | c.11307C>T p.I3769= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as COSV67472428; called by muse, mutect2, varscan2
- MUC17 | c.12315C>T p.F4105= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV100072684, COSV60282357; called by muse, mutect2, varscan2
- MYH2 | c.3279C>T p.I1093= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV55447206; called by muse, mutect2, varscan2
- MYOM1 | c.51C>T p.Y17= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV55300247; called by muse, mutect2, varscan2
- NDRG4 | c.744C>T p.S248= (on ENST00000570248 / NM_001378344.1; = p.S280= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs267604588, COSV50751135; called by muse, mutect2, varscan2
- NOL4 | c.435C>T p.F145= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV52351934; called by muse, mutect2, varscan2
- NPAS1 | c.831G>A p.R277= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV71384309; called by muse, mutect2, varscan2
- NPBWR1 | c.912C>T p.P304= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100488284; called by muse, mutect2, varscan2
- NPC1L1 | c.927C>T p.P309= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as rs1017546573, COSV56922987; called by muse, mutect2, varscan2
- NPLOC4 | c.1185C>T p.V395= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV58619064; called by muse, mutect2, varscan2
- NPY1R | c.96T>C p.D32= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV56716150; called by muse, mutect2, varscan2
- OAS1 | c.402C>T p.F134= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs1284104812, COSV52534234; called by muse, mutect2, varscan2
- OR10H5 | c.744G>A p.V248= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV58277708; called by muse, mutect2, varscan2
- OR10J3 | c.621C>T p.V207= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as COSV59954103, COSV59954110; called by muse, varscan2
- OR1C1 | c.312C>T p.F104= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs373351363, COSV68715780; called by muse, mutect2, varscan2
- OR2G2 | c.105G>A p.L35= | Silent (SNP) | VAF 83/234 reads (35%) | catalogued as COSV60742180, COSV60742741; called by muse, mutect2, varscan2
- OR4E2 | c.795C>T p.F265= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV57732247; called by muse, mutect2, varscan2
- OR52E4 | c.282C>T p.I94= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as COSV57625985; called by muse, mutect2, varscan2
- OR52E8 | c.165C>T p.I55= | Silent (SNP) | VAF 69/207 reads (33%) | catalogued as COSV66205665, COSV66211696; called by muse, mutect2, varscan2
- OR52L1 | c.460C>T p.L154= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV59989020; called by muse, mutect2, varscan2
- OR5K1 | c.363C>T p.D121= | Silent (SNP) | VAF 69/241 reads (29%) | catalogued as rs1466424234, COSV60305233; called by muse, mutect2, varscan2
- OR5P2 | c.759C>T p.F253= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as COSV61491210; called by muse, mutect2, varscan2
- OR5R1 | c.108G>A p.L36= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV56573475; called by muse, mutect2, varscan2
- OR5T3 | c.180G>A p.L60= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV57381456, COSV57382362; called by muse, mutect2, varscan2
- OR6C65 | c.906C>T p.F302= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV65569321; called by muse, mutect2, varscan2
113 further variants in this file (0 protein-altering or splice-affecting, 96 silent, 17 other) are not listed here.
